Somatic mutation profile of tumor specimen C3L-01703-02 (aliquot CPT0094940010_1) from CPTAC case C3L-01703, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 62.7 years (22,902 days).
Specimen C3L-01703-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebaafc8f-cf36-4edd-9ca9-591cf0273e9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01703-31 (Blood Derived Normal), aliquot CPT0094970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/827c4fe4-b752-4a46-89ca-88d4bad2ed45

The open-access MAF lists 48 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 9, Nonsense Mutation 2, 3'UTR 1, Intron 1, 5'UTR 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 79/714 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 54/593 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CCDC198 | c.80C>G p.S27W | Missense Mutation (SNP) | VAF 78/844 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as rs201357909, COSV53602337; called by muse, mutect2
- DNAH8 | c.7991C>A p.S2664Y | Missense Mutation (SNP) | VAF 42/498 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59436575; called by muse, mutect2
- DVL3 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 41/320 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1481467926, COSV57457221; called by muse, mutect2, varscan2
- FADS2 | c.391G>A p.V131M | Missense Mutation (SNP) | VAF 107/1020 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs767852784, COSV53898514; called by muse, mutect2
- GAS2L1 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs149600937; called by muse, mutect2, varscan2
- GIPC3 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated, low confidence (0.1); catalogued as rs1161586962; called by muse, mutect2
- GPR157 | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 44/347 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV66233565; called by muse, mutect2, varscan2
- KCNA3 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 76/557 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871236, COSV63901810; called by muse, mutect2, varscan2
- KIAA0586 | c.3535C>T p.Q1179* (on ENST00000619416 / NM_001244190.2; = p.Q1118* on NM_014749.5) | Nonsense Mutation (SNP) | VAF 66/593 reads (11%) | catalogued as rs373763986, COSV99709144; called by muse, mutect2, varscan2
- MNS1 | c.1421T>A p.I474N | Missense Mutation (SNP) | VAF 21/280 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV53068991; called by muse, mutect2
- NT5DC2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV58739494; called by muse, mutect2, varscan2
- RFPL1 | c.452G>A p.C151Y | Missense Mutation (SNP) | VAF 61/473 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1356963184; called by muse, mutect2, varscan2
- SCN1A | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 72/514 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as rs184524479, COSV57677537; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC18A3 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 88/738 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as COSV60320455; called by muse, mutect2, varscan2
- TKT | c.1411C>T p.R471W | Missense Mutation (SNP) | VAF 73/554 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201786364; called by muse, mutect2, varscan2
- ZNF329 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs749321833; called by muse, mutect2, varscan2
- AL592490.1 | c.1075T>C p.Y359H | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- ARHGAP21 | c.3871A>T p.N1291Y | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP36 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- C17orf98 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 42/472 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2
- CHDH | c.1051A>T p.T351S | Missense Mutation (SNP) | VAF 30/313 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.172); called by muse, mutect2
- COG5 | c.1711G>T p.A571S (on ENST00000347053 / NM_001379512.1; = p.A592S on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/595 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2
- ERBB4 | c.1211T>C p.I404T | Missense Mutation (SNP) | VAF 60/642 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2
- MED24 | c.1584G>T p.W528C | Missense Mutation (SNP) | VAF 38/674 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR51V1 | c.765C>A p.Y255* | Nonsense Mutation (SNP) | VAF 41/301 reads (14%) | called by muse, mutect2, varscan2
- OR56A3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- PRAG1 | c.1473C>G p.S491R | Missense Mutation (SNP) | VAF 65/412 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- PRRC1 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.021); called by muse, mutect2
- RASAL1 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 41/383 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SSX7 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 105/546 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TGFBR2 | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 78/751 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAK1 | c.2423A>G p.N808S | Missense Mutation (SNP) | VAF 51/400 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- TSSK1B | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 52/464 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- GNE | c.453C>T p.A151= (on ENST00000396594 / NM_001128227.3; = p.A120= on NM_005476.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/603 reads (12%) | called by muse, mutect2, varscan2
- PRAG1 | c.1428C>T p.V476= | Silent (SNP) | VAF 47/324 reads (15%) | catalogued as COSV58165677; called by muse, varscan2
- SLC6A2 | c.624G>A p.T208= | Silent (SNP) | VAF 61/623 reads (10%) | catalogued as rs773801761, COSV54913783; ClinVar: likely benign; called by muse, mutect2
- TDRD15 | c.3573C>T p.S1191= | Silent (SNP) | VAF 22/283 reads (8%) | catalogued as rs563732296; called by muse, mutect2
- TRIM41 | c.555G>A p.Q185= | Silent (SNP) | VAF 39/346 reads (11%) | catalogued as rs900162156; called by muse, mutect2, varscan2
- TRIM42 | c.858C>T p.D286= | Silent (SNP) | VAF 92/947 reads (10%) | catalogued as rs749484750; called by muse, mutect2
- TRIO | c.5835G>A p.S1945= | Silent (SNP) | VAF 56/548 reads (10%) | catalogued as rs368260455; called by muse, mutect2, varscan2
- ZNF644 | c.726G>A p.T242= | Silent (SNP) | VAF 99/873 reads (11%) | catalogued as rs148356542, COSV61347837; called by muse, mutect2, varscan2
- ZNF808 | c.1296T>C p.C432= | Silent (SNP) | VAF 61/562 reads (11%) | catalogued as rs1324959165; called by muse, mutect2, varscan2
- BOD1P2 | n.67C>T | RNA (SNP) | VAF 6/85 reads (7%) | catalogued as rs1317540076; called by muse, mutect2
- CHMP2B | c.*22T>A | 3'UTR (SNP) | VAF 42/483 reads (9%) | called by muse, mutect2
- DUS4L-BCAP29 | c.-291C>T | 5'UTR (SNP) | VAF 48/482 reads (10%) | catalogued as rs973411750; called by muse, mutect2
- STX18 | c.237-2460A>G | Intron (SNP) | VAF 44/506 reads (9%) | catalogued as rs1222873976; called by muse, mutect2
